Gene-level copy-number profile of tumor specimen TCGA-VQ-A91Z-01A from TCGA case TCGA-VQ-A91Z, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.5 years (24,652 days).
Specimen TCGA-VQ-A91Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e332cddc-8d1b-4e72-a6e6-512daf17775e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41217b86-c18f-4dd3-a32e-a7222b3db965

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 154; copy number 1: 1,984; copy number 2: 29,929; copy number 3: 16,967; copy number 4: 5,589; copy number 5: 890; copy number 6: 3,568; copy number 7: 731.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91Z-01A-11D-A40Z-01): tumor purity 0.77, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 153 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:54,456,317–54,671,446, 4 genes (within-gene range 0–2): SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1.
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.
- chr9:19,957,394–31,645,160, 144 genes (broad region; genes not listed).
- chr10:66,926,036–67,101,551, 1 gene (within-gene range 0–2): LRRTM3.
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,189 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–7 (broad region; genes not listed).
- chr6:95,504,182–97,140,754, 21 genes, copy number 6 (within-gene range 3–6): CYCSP17, MANEA-DT, MANEA, AL607077.1, AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32.
- chr6:170,282,206–170,738,536, 14 genes, copy number 5 (within-gene range 3–5): DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr9:32,293,558–38,147,561, 237 genes, copy number 6 (broad region; genes not listed).
- chr9:77,580,245–84,004,074, 76 genes, copy number 6 (broad region; genes not listed).
- chr9:86,374,966–93,320,572, 147 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:18,467,172–22,276,526, 116 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr13:23,570,370–86,462,734, 860 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr13:88,978,447–114,337,626, 370 genes, copy number 6–7 (broad region; genes not listed).
- chr17:81,244,811–81,295,547, 1 gene, copy number 5 (within-gene range 4–5): SLC38A10.
- chr17:81,303,771–83,095,122, 117 genes, copy number 5 (broad region; genes not listed).
- chr20:833,715–16,053,197, 267 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,099. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
